Gene-level copy-number profile of tumor specimen ALCH-AEYL-TTP1-A from ALCHEMIST case ALCH-AEYL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 48.0 years (17,531 days).
Specimen ALCH-AEYL-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 495140b3-0cb2-4dea-83c4-ce373f1a6f40.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEYL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/200f755d-6b07-4d50-baed-c68e4d406503

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 57,509; copy number 3: 891; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
